Somatic mutation profile of tumor specimen 0DLX5C from CCDI case PBBZWA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,031 days).
Specimen 0DLX5C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd14a7cc-fdee-40ba-ac48-a65fdcf5fd1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7567b4f-9d3b-4480-9c44-72a31cf5fa3f

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 4, Silent 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC160 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 81/453 reads (18%) | catalogued as rs747022373; called by muse, mutect2, varscan2
- EMC1 | c.2513A>G p.Y838C | Missense Mutation (SNP) | VAF 68/486 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776468170; called by muse, mutect2, varscan2
- PCDHGA11 | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs1442545718; called by muse, mutect2
- PHRF1 | c.1384C>T p.R462W (on ENST00000264555 / NM_001286581.2; = p.R461W on NM_020901.4) | Missense Mutation (SNP) | VAF 34/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774164080, COSV52752453; called by muse, mutect2
- RNF213 | c.8687G>A p.R2896Q | Missense Mutation (SNP) | VAF 148/407 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760665858; called by muse, mutect2, varscan2
- STAG2 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 30/310 reads (10%) | catalogued as COSV54354732, COSV54371270, COSV54374249; called by muse, mutect2
- TOPBP1 | c.3839G>A p.R1280H | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780031847; called by muse, mutect2, varscan2
- VEPH1 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 141/365 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1246186678, COSV62877246; called by muse, mutect2, varscan2
- CEP170 | c.4060-7C>G | Splice Region (SNP) | VAF 25/295 reads (8%) | called by muse, mutect2
- LRP1 | c.12398_12399insGTGC p.S4134Cfs*3 | Frame Shift Ins (INS) | VAF 64/686 reads (9%) | called by mutect2, pindel
- ARHGEF33 | c.2199C>T p.G733= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- SNIP1 | c.537G>A p.R179= | Silent (SNP) | VAF 58/620 reads (9%) | called by muse, mutect2
- MED13L | c.2996+60A>T | Intron (SNP) | VAF 70/258 reads (27%) | called by muse, mutect2
- TMEM86B | c.51+19G>T | Intron (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- TMEM86B | c.51+17C>T | Intron (SNP) | VAF 18/378 reads (5%) | called by muse, mutect2
- TPM2 | c.564-46C>T | Intron (SNP) | VAF 18/266 reads (7%) | catalogued as rs781408147, COSV61405903; called by muse, mutect2
